Surgical pathology report (de-identified scan), TCGA case TCGA-SR-A6MX, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Tufts Medical Center, specimen TCGA-SR-A6MX-05A (Additional - New Primary).

[page 1 of 2]
Specimen:

Procedure:

Accessioned:

Reported:

Submitting Phys:

Patient:

Medical Record #:

DOB/Age/Sex:

Location/Client:

Account #:

(Age:) M

Surgical Pathology Report

**** Procedures/Addenda Added ****

Final Diagnosis

A. PERITONEAL NODULE, EXCISION:

- POSITIVE FOR PARAGANGLIOMA, CONSISTENT WITH PERITONEAL IMPLANT.
- IMMUNOHISTOCHEMICAL STAINS ARE POSITIVE FOR CHROMOGRANIN A AND SYNAPTOPHYSIN.

B. ABDOMINAL TUMOR, EXCISION:

- PARAGANGLIOMA, MULTIPLE EXTRAHEPATIC AND INTRAHEPATIC NODULES, UP TO 2.5 CM. SEE COMMENT.
- IMMUNOHISTOCHEMICAL STAIN FOR TYROSINE HYDROXYLASE IS STRONGLY POSITIVE IN ALL TUMOR CELLS
- IMMUNOHISTOCHEMICAL STAIN FOR S-100 HIGHLIGHTS NUMEROUS SUSTENTACULAR CELLS SURROUNDING TUMOR CELL NESTS.
- IMMUNOHISTOCHEMICAL STAIN FOR KI-67 SHOWS A 7% LABELING INDEX BASED ON COMPUTER-ASSISTED COUNTS OF TWELVE 20x FIELDS OF HIGHEST LABELING (SEE VIAS REPORT BELOW)
- IMMUNOHISTOCHEMICAL STAINS FOR CD34 AND CD163 AND RETICULIN STAIN WERE ALSO USED IN INTERPRETATION.

COMMENT: The tumor nodules extensively infiltrate subcapsular areas of the liver parenchyma, consistent with local recurrence and invasive implants at the site of the primary tumor removed in the distant past. See radiology report.

Comments

All controls show appropriate reactivity.

*ICD0-3
Paraganglioma, extra-adrenal malignant
Site: liver C22.0
8693/3
7/15/15*

*****Report Electronically Signed By**

This certifies that the pathologist named above has personally conducted a microscopic examination (or gross examination only, where stated) of the described specimen(s) and has rendered or confirmed the final diagnosis(es).

Immunohistochemistry

Ki-67 Proliferation Index: 7%

Morphometric analysis for quantitation of Ki-67 signal is performed by computer-assisted technology on Block B2.

Ki-67 Assay: The primary antibody used is anti-Ki-67 (30-9) directed against the C-terminal portion of Ki-67 antigen and is performed on the automated slide stainer.

Detection of all primary antibodies is via an indirect, biotin-free system for detecting mouse IgG, mouse IgM and rabbit primary antibodies. The kit is intended to identify targets by immunohistochemistry in sections of formalin-fixed, paraffin-embedded tissue that are stained on the Series automated slide stainers.

[page 2 of 2]
Immunohistochemical staining performed in this case may involve reagents labeled as analyte specific reagents. For these cases: This test was developed and its performance characteristics determined by It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

Intra-Operative Consultation with Frozen Section

AFS. PERITONEAL NODULE, FS:

- DEFERRED PENDING PERMANENT SECTIONS.

Clinical History

{Not Provided}

Pre-Operative Diagnosis

{Not Provided}

Post-Operative Diagnosis

{Not Provided}

Gross Description

A. PERITONEAL NODULE (FRESH): The specimen, labeled with the patient's name, and medical record number, consists of a single white-tan nodule (0.3 x 0.2 x 0.3 cm). The specimen was submitted for intraoperative consultation using frozen section.

B. LIVER (FRESH): The specimen, labeled with the patient's name, and medical record number, consists of multiple fragments of red-brown liver parenchyma and associated fibrofatty tissue (9 x 5.5 x 2.5 cm in aggregate). Within the aggregate are several separate extrahepatic and intrahepatic tan-white nodules, measuring up to 2.5 cm in greatest dimension. Representative sections of the tan-white nodules and liver parenchyma are submitted in cassettes B1-8.

Immunohistochemical staining performed in this case may involve reagents labeled as analyte specific reagents. For these cases: This test was developed and its performance characteristics determined by It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

2nd Primary submitted to FCGA for this case.
- para 6 @retroperitoneum
- para 8 epidural w/ met from skull

Local/Synchronous Primary	Noted	✓

Source: NCI Genomic Data Commons file e9321f1d-e18d-4262-9f13-1bdcab82f8c1 (TCGA-SR-A6MX.DB0B2D04-686F-4935-A5E5-DEB421367016.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).